TCGA case TCGA-BP-5199 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d30f460b-8e85-4eb4-83b8-0a5d8bf4d10d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 58.2 years (21,256 days); Year of diagnosis: 2006; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G4; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 4.
2. Combined small cell carcinoma: ICD-O-3 morphology code: 8045/3; Tissue or organ of origin: Brain, NOS; Laterality: Left; Classification of tumor: Synchronous primary.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin + Etoposide; Days to treatment start: -77 days; Treatment anatomic sites: Body, total.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 38 days; Treatment anatomic sites: Locoregional Site.

Follow-up (1 entry)
- Days to follow up: 1,355 days (3.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Leukocytes: Normal.
- Calcium: Low.
- Platelets: Normal.
- Hemoglobin: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BP-5199-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1.3; Shortest dimension: 0.3.
  Slide TCGA-BP-5199-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-BP-5199-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-BP-5199-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BP-5199-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.4; Intermediate dimension: 0.8; Shortest dimension: 0.1.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: Yes.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Brain; Other malignancy histological type: Lung Small Cell Squamous Cell Carcinoma.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -96.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form, Drug treatment, Administered drug: Pharmaceutical therapy drug name: Etoposide, Cisplatin.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy L lung cancer with brian mets treated with etoposide and cisplatin and locoregional radiation.
- Prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,355 days; disease-specific survival: no event (censored), 1,355 days; progression-free interval: no event (censored), 1,355 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-BP-5199-01): tumor purity 0.49, ploidy 3.85, whole-genome doublings 1 (call status: legacy_maf_call).
